TCGA case TCGA-AX-A1CF — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/20dcf91a-0529-4e96-99a2-362a41fbe4a4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (2)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 69.3 years (25,300 days); Year of diagnosis: 2004; Method of diagnosis: Biopsy; FIGO stage: Stage IVB; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 2,337 days (6.4 years).
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 50.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 0.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 7.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Megestrol Acetate + Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 1,037 days (2.8 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,588 days (4.3 years); Course number: 1; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,799 days (4.9 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Persistent Disease; Days to treatment start: 2,052 days (5.6 years).
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Tamoxifen; Timepoint category: Prior to Diagnosis.
2. Diagnosis record without a diagnosis name: Age at diagnosis: 71.7 years (26,175 days); Days to diagnosis: 875 days (2.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS.

Follow-up (3 entries)
- Day 875 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 2,337 days (6.4 years); Disease response: With Tumor.
- Peritoneal washing results: Positive; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79 kg; Height: 150 cm; BMI: 35.1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AX-A1CF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 130 mg.
  Slide TCGA-AX-A1CF-01A-01-TS1: Section location: Top; Percent tumor cells: 73; Percent tumor nuclei: 75; Percent normal cells: 20; Percent necrosis: 2; Percent stromal cells: 5; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AX-A1CF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AX-A1CF-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 50 mg.
  Slide TCGA-AX-A1CF-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent normal cells: 100.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open.
- Follow-up form: History tamoxifen use: Former User; History colorectal cancer: No; Tumor status: With tumor; New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Tamoxifen & Megace; Therapy regimen: Progression.
- Drug treatment 2: Regimen number: 3; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Persistent.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Adriamycin; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,337 days; disease-specific survival: no event (censored), 2,337 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 875 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AX-A1CF-01A-11D-A134-01): tumor purity 0.76, ploidy 1.82, whole-genome doublings 0.
